Somatic mutation profile of tumor specimen HCM-WCMC-0675-C67-02A (aliquot HCM-WCMC-0675-C67-02A-10D-A83U-36) from HCMI case HCM-WCMC-0675-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage X; Tumor grade: GX; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-WCMC-0675-C67-02A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 867faa06-5d6d-41fc-95a5-53f930d34b8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0675-C67-10A (Blood Derived Normal), aliquot HCM-WCMC-0675-C67-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/004e6511-73e1-432a-9f17-4a69f1122fda

The open-access MAF lists 129 somatic variants for this specimen: 88 protein-altering or splice-affecting, 33 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 33, Intron 7, Nonsense Mutation 4, Frame Shift Del 2, In Frame Del 2, Frame Shift Ins 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11A1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 77/638 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs121912811, CS021747, COSV51433766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 250/336 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 97/332 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60788908, COSV60805381; called by muse, mutect2, varscan2
- APH1B | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 128/434 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1285108399; called by muse, mutect2, varscan2
- BCLAF3 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 117/451 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.127); catalogued as rs751543626, COSV61413804; called by muse, mutect2, varscan2
- BRINP3 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 504/1119 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.202); catalogued as COSV100818385, COSV66540992; called by muse, mutect2, varscan2
- CACNA1E | c.6676C>T p.R2226C (on ENST00000367573 / NM_001205293.3; = p.R2183C on NM_000721.4) | Missense Mutation (SNP) | VAF 72/822 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs746785304, COSV100705332, COSV100705796; called by muse, mutect2
- CCDC168 | c.3228del p.K1076Nfs*14 | Frame Shift Del (DEL) | VAF 74/459 reads (16%) | catalogued as rs765903699; called by mutect2, varscan2
- COL5A1 | c.4043G>C p.G1348A | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1060502252, COSV65665157; ClinVar: uncertain significance; called by muse, varscan2
- CYFIP1 | c.2588G>A p.R863Q | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs770002354; called by muse, mutect2, varscan2
- DCAF15 | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 39/383 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.961); catalogued as rs1448841032; called by muse, mutect2, varscan2
- DCLK1 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 72/1338 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs745600254, COSV55206432; called by muse, mutect2
- DNMBP | c.4126C>T p.R1376C | Missense Mutation (SNP) | VAF 180/623 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375209058; called by muse, mutect2, varscan2
- EGF | c.2528A>G p.Y843C | Missense Mutation (SNP) | VAF 263/807 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs1212404748, COSV54480924; called by muse, mutect2, varscan2
- ERICH3 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 132/890 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV58620295; called by muse, mutect2, varscan2
- FBN1 | c.3455C>T p.A1152V | Missense Mutation (SNP) | VAF 101/582 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs539103389, CM096445, COSV57323932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMCN1 | c.13969G>A p.E4657K | Missense Mutation (SNP) | VAF 82/1402 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1183965155, COSV54890148; called by muse, mutect2
- HPR | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 77/448 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201688913; called by muse, mutect2, varscan2
- KCP | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as rs981064215; called by muse, mutect2, varscan2
- KLB | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 91/877 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs567666148, COSV99962575; called by muse, mutect2, varscan2
- MAG | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 67/462 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs756136921, COSV62698782; called by muse, mutect2, varscan2
- PCDH15 | c.4996G>A p.A1666T (on ENST00000644397 / NM_001354429.2; = p.A1608T on NM_001142771.2) | Missense Mutation (SNP) | VAF 326/1221 reads (27%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV100902198; called by muse, mutect2, varscan2
- PHF21B | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 132/403 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs1355672081, COSV100503463, COSV57559322; called by muse, mutect2, varscan2
- PLXNB2 | c.3532G>A p.G1178S | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs745854880; called by muse, varscan2
- PLXND1 | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 94/294 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.803); catalogued as rs775659642, COSV100139940; called by muse, mutect2, varscan2
- POLG | c.3646G>A p.E1216K | Missense Mutation (SNP) | VAF 20/492 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1469896894; called by muse, mutect2
- PRDM4 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 122/753 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs757375674, COSV57307145; called by muse, mutect2, varscan2
- PROKR2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 75/511 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146544539; ClinVar: likely benign; called by muse, varscan2
- RIMKLA | c.1136_1138del p.N379del | In Frame Del (DEL) | VAF 62/511 reads (12%) | catalogued as rs1360884924; called by pindel, varscan2
- RYR2 | c.7706T>C p.I2569T | Missense Mutation (SNP) | VAF 323/808 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as rs761497764, COSV63685387; called by muse, mutect2, varscan2
- RYR2 | c.10265A>G p.Q3422R | Missense Mutation (SNP) | VAF 237/600 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV63724073; called by muse, mutect2, varscan2
- SEC24B | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 45/806 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.122); catalogued as COSV54508310; called by muse, mutect2
- SOX8 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs555677616; called by muse, mutect2
- TNN | c.3827C>T p.P1276L | Missense Mutation (SNP) | VAF 114/918 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747233076; called by muse, mutect2, varscan2
- TSC1 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 290/832 reads (35%) | catalogued as COSV99036974; called by muse, mutect2, varscan2
- TSHZ2 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 99/765 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs757806984, COSV61589633; called by muse, mutect2, varscan2
- TTN | c.34813C>T p.P11605S (on ENST00000591111; = p.P10678S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/579 reads (14%) | PolyPhen benign (0); catalogued as rs1560102675; called by muse, mutect2, varscan2
- UTP3 | c.1249A>G p.K417E | Missense Mutation (SNP) | VAF 179/594 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191703808; called by muse, mutect2, varscan2
- ZNF274 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1432256836; called by muse, mutect2
- ADCY10 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 68/718 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANO4 | c.263C>T p.S88L (on ENST00000392977 / NM_001286615.2; = p.S53L on NM_178826.4) | Missense Mutation (SNP) | VAF 168/1021 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- C3orf84 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 52/361 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CA13 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 310/744 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPF | c.5983C>G p.Q1995E | Missense Mutation (SNP) | VAF 142/1257 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNOT11 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 106/578 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL3 | c.2165T>C p.L722P | Missense Mutation (SNP) | VAF 20/662 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CUZD1 | c.1466G>A p.R489K | Missense Mutation (SNP) | VAF 124/1237 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CWF19L2 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 153/1228 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DCLK3 | c.436_437dup p.E147Gfs*33 | Frame Shift Ins (INS) | VAF 57/466 reads (12%) | called by mutect2, varscan2
- DCSTAMP | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 99/967 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DNAJC2 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 50/1149 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- DNER | c.558_560del p.V187del | In Frame Del (DEL) | VAF 41/337 reads (12%) | called by mutect2, pindel, varscan2
- EIF4B | c.1348A>G p.T450A | Missense Mutation (SNP) | VAF 106/498 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ERBB2 | c.696dup p.T233Hfs*2 | Frame Shift Ins (INS) | VAF 94/691 reads (14%) | called by mutect2, pindel, varscan2
- ESYT3 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 76/493 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM83C | c.2045T>C p.L682P | Missense Mutation (SNP) | VAF 90/673 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLRT3 | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 94/1020 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2
- GFOD2 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 64/414 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- HMCN1 | c.5073A>T p.E1691D | Missense Mutation (SNP) | VAF 174/1507 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HPX | c.973C>A p.Q325K | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- IGKV2D-24 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 202/722 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- IMPDH2 | c.549A>T p.E183D | Missense Mutation (SNP) | VAF 74/594 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IQGAP1 | c.1813G>C p.E605Q | Missense Mutation (SNP) | VAF 77/661 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KDR | c.3085C>A p.L1029M | Missense Mutation (SNP) | VAF 67/568 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF5A | c.1622G>A p.G541E | Missense Mutation (SNP) | VAF 108/641 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KLK15 | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 238/456 reads (52%) | called by muse, mutect2, varscan2
- KLKB1 | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 111/511 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KNL1 | c.3517G>T p.A1173S (on ENST00000346991 / NM_170589.5; = p.A1147S on NM_144508.5) | Missense Mutation (SNP) | VAF 127/714 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- LAMA3 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 100/435 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRFN5 | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 226/511 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP3K10 | c.1598G>C p.G533A | Missense Mutation (SNP) | VAF 111/368 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NECTIN1 | c.1492G>T p.A498S | Missense Mutation (SNP) | VAF 60/424 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NRK | c.4007T>C p.I1336T | Missense Mutation (SNP) | VAF 158/379 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- OR2T4 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 71/1448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR8B3 | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 191/739 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARD3 | c.2695G>T p.E899* | Nonsense Mutation (SNP) | VAF 204/974 reads (21%) | called by muse, mutect2, varscan2
- PHF11 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 160/661 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PPARG | c.1169A>G p.D390G (on ENST00000287820 / NM_015869.5; = p.D360G on NM_005037.7) | Missense Mutation (SNP) | VAF 158/1072 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- PRKCE | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 227/603 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PSME4 | c.3484A>C p.K1162Q | Missense Mutation (SNP) | VAF 131/471 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- SBNO2 | c.3479G>A p.R1160Q | Missense Mutation (SNP) | VAF 57/552 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCMH1 | c.1421del p.S474Yfs*5 (on ENST00000326197 / NM_001031694.2; = p.S427Yfs*5 on NM_012236.4) | Frame Shift Del (DEL) | VAF 98/725 reads (14%) | called by mutect2, pindel, varscan2
- SEMA3G | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 39/378 reads (10%) | called by muse, mutect2, varscan2
- SNCAIP | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 96/675 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TOPAZ1 | c.427A>T p.T143S | Missense Mutation (SNP) | VAF 90/724 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- ZC3HAV1 | c.2257A>C p.N753H | Missense Mutation (SNP) | VAF 69/655 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- ZCCHC24 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 95/357 reads (27%) | SIFT tolerated, low confidence (0.68); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ZNF214 | c.681T>G p.I227M | Missense Mutation (SNP) | VAF 115/620 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKR1B15 | c.996C>T p.F332= | Silent (SNP) | VAF 128/596 reads (21%) | called by muse, mutect2, varscan2
- AMFR | c.189G>A p.P63= | Silent (SNP) | VAF 200/621 reads (32%) | catalogued as rs1402738438, COSV51921384; called by muse, mutect2, varscan2
- ARHGEF18 | c.474C>G p.T158= (on ENST00000359920 / NM_001130955.2; = p.T54= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/269 reads (21%) | called by muse, mutect2, varscan2
- C2CD2L | c.171G>A p.A57= | Silent (SNP) | VAF 308/633 reads (49%) | catalogued as rs565781414; called by muse, mutect2, varscan2
- CC2D2B | c.2364C>T p.A788= | Silent (SNP) | VAF 126/444 reads (28%) | called by muse, mutect2, varscan2
- CDHR3 | c.690C>T p.N230= | Silent (SNP) | VAF 115/522 reads (22%) | catalogued as rs368294260; called by muse, mutect2, varscan2
- COL5A1 | c.1896C>T p.F632= | Silent (SNP) | VAF 50/360 reads (14%) | catalogued as rs376478864; ClinVar: conflicting interpretations of pathogenicity / benign; called by muse, mutect2, varscan2
- DDX39A | c.1275G>A p.Q425= | Silent (SNP) | VAF 93/401 reads (23%) | called by muse, mutect2, varscan2
- EFCC1 | c.1359G>T p.L453= | Silent (SNP) | VAF 64/499 reads (13%) | called by muse, mutect2, varscan2
- FBXL7 | c.1284C>T p.F428= | Silent (SNP) | VAF 23/716 reads (3%) | called by muse, mutect2
- GAK | c.3724C>T p.L1242= | Silent (SNP) | VAF 42/303 reads (14%) | catalogued as rs1480840279; called by muse, mutect2, varscan2
- GALNT9 | c.918G>A p.P306= | Silent (SNP) | VAF 28/356 reads (8%) | catalogued as rs938904169, COSV61101484; called by muse, mutect2
- GPR180 | c.708G>A p.G236= | Silent (SNP) | VAF 135/924 reads (15%) | catalogued as rs768458574; called by muse, mutect2, varscan2
- H2BC21 | c.288G>A p.Q96= | Silent (SNP) | VAF 113/1036 reads (11%) | called by muse, mutect2, varscan2
- HCN4 | c.324C>A p.G108= | Silent (SNP) | VAF 57/228 reads (25%) | catalogued as COSV56081063; called by muse, mutect2, varscan2
- HTT | c.3078T>C p.C1026= | Silent (SNP) | VAF 275/745 reads (37%) | called by muse, mutect2, varscan2
- KCNF1 | c.1255C>T p.L419= | Silent (SNP) | VAF 108/295 reads (37%) | called by muse, mutect2, varscan2
- KIAA1755 | c.1911C>T p.D637= | Silent (SNP) | VAF 62/616 reads (10%) | catalogued as rs112826952; called by muse, mutect2, varscan2
- KL | c.234C>T p.G78= | Silent (SNP) | VAF 168/617 reads (27%) | called by muse, mutect2, varscan2
- MTMR7 | c.1404C>T p.A468= | Silent (SNP) | VAF 42/892 reads (5%) | catalogued as rs187644767; called by muse, mutect2
- NIT2 | c.240C>T p.L80= | Silent (SNP) | VAF 76/476 reads (16%) | called by muse, mutect2, varscan2
- NR2E3 | c.729C>T p.S243= | Silent (SNP) | VAF 36/197 reads (18%) | catalogued as rs747947987, COSV58909507; called by muse, mutect2, varscan2
- PANX2 | c.1914G>A p.E638= | Silent (SNP) | VAF 104/332 reads (31%) | catalogued as rs1025554683; called by muse, mutect2, varscan2
- PCDHB9 | c.1770G>A p.V590= | Silent (SNP) | VAF 78/469 reads (17%) | called by muse, mutect2, varscan2
- RAPSN | c.6G>A p.G2= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as rs201291481; called by muse, mutect2, varscan2
- SCYL3 | c.1032G>A p.Q344= | Silent (SNP) | VAF 156/1459 reads (11%) | called by muse, mutect2, varscan2
- SEMA3G | c.2055G>T p.P685= | Silent (SNP) | VAF 39/378 reads (10%) | catalogued as COSV51594006; called by muse, mutect2, varscan2
- SLC28A3 | c.648A>G p.L216= | Silent (SNP) | VAF 83/423 reads (20%) | catalogued as rs762486318; called by muse, mutect2, varscan2
- SPATA7 | c.618A>G p.T206= | Silent (SNP) | VAF 480/1093 reads (44%) | catalogued as rs576385745; called by muse, mutect2, varscan2
- SYCE1L | c.6G>A p.A2= | Silent (SNP) | VAF 70/496 reads (14%) | catalogued as rs908248831; called by mutect2, varscan2
- WARS2 | c.885G>A p.A295= | Silent (SNP) | VAF 259/759 reads (34%) | catalogued as rs946355135, COSV52477659; called by muse, mutect2, varscan2
- ZFC3H1 | c.528G>A p.L176= | Silent (SNP) | VAF 374/1682 reads (22%) | called by muse, mutect2, varscan2
- ZIC5 | c.120G>A p.A40= | Silent (SNP) | VAF 83/658 reads (13%) | catalogued as rs1228981414; called by muse, mutect2, varscan2
- APOB | c.2436+80C>T | Intron (SNP) | VAF 137/872 reads (16%) | catalogued as rs749924496; called by muse, mutect2, varscan2
- MIR4435-2HG | n.161-61979C>G | Intron (SNP) | VAF 77/600 reads (13%) | catalogued as rs996073812; called by muse, mutect2
- SDF4 | c.892-89A>G | Intron (SNP) | VAF 83/270 reads (31%) | catalogued as rs576116710; called by muse, mutect2, varscan2
- SH2B3 | c.733-11808C>T | Intron (SNP) | VAF 90/978 reads (9%) | called by muse, mutect2
- TMTC3 | c.*2794A>G | 3'UTR (SNP) | VAF 166/888 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.10361-4267A>G | Intron (SNP) | VAF 100/662 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.10361-4850C>A | Intron (SNP) | VAF 72/564 reads (13%) | called by muse, mutect2, varscan2
- UNC13B | c.762-7136G>A | Intron (SNP) | VAF 135/679 reads (20%) | called by muse, mutect2, varscan2
